Surgical pathology report (de-identified scan), TCGA case TCGA-61-1724, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-61-1724-01A (Primary Tumor).

[page 1 of 2]
FINAL DIAGNOSIS:

PART 1: OMENTUM, OMENTECTOMY -

- A. METASTATIC HIGH-GRADE SEROUS PAPILLARY CARCINOMA (SEE COMMENT 1, 2,3)
- B. LYMPHOVASCULAR INVASION IDENTIFIED.

PART 2: ABDOMINAL WALL, LEFT UPPER, EXCISION -

METASTATIC HIGH-GRADE SEROUS PAPILLARY CARCINOMA.

PART 3: CALCIFORM LIGAMENT TUMOR, EXCISION -

METASTATIC HIGH-GRADE SEROUS PAPILLARY CARCINOMA.

PART 4: SPLEEN, SPLENECTOMY -

- A. METASTATIC HIGH-GRADE SEROUS PAPILLARY CARCINOMA INVOLVING PERISPLENIC ADIPOSE TISSUE AND SPLENIC CAPSULE.
- B. LYMPHOVASCULAR INVASION IDENTIFIED.

PART 5: UTERUS, CERVIX, BILATERAL ADNEXA, RECTUM AND SIGMOID COLON, TOTAL ABDOMINAL HYSTERECTOMY, BILATERAL SALPINGO-OOPHORECTOMY AND BOWEL RESECTION -

- A. HIGH GRADE SEROUS PAPILLARY CARCINOMA INVOLVING RIGHT AND LEFT OVARIES.
- B. RIGHT AND LEFT FALLOPIAN TUBES WITH METASTATIC SEROUS PAPILLARY CARCINOMA INVOLVING SEROSA.
- C. METASTATIC HIGH-GRADE SEROUS PAPILLARY CARCINOMA INVOLVING SEROSA OF THE UTERUS.
- D. LYMPHOVASCULAR SPACE INVASION PRESENT INVOLVING CERVICAL STROMA.
- E. ENDOMETRIAL POLYP.
- F. MULTIPLE LEIOMYOMATA, LARGEST MEASURING 4.5 CM.
- G. MICROGLANDULAR HYPERPLASIA.
- H. METASTATIC HIGH-GRADE SEROUS PAPILLARY CARCINOMA INVOLVING SEROSA OF THE COLON AND ALSO PRESENT AT ONE MARGIN OF RESECTION (SLIDE 5W).

PART 6: LYMPH NODE, LEFT PELVIC, BIOPSY -

METASTATIC HIGH-GRADE SEROUS PAPILLARY CARCINOMA.

PART 7: LYMPH NODE, RIGHT PELVIC, BIOPSY -

- A. THREE LYMPH NODES, POSITIVE FOR METASTATIC HIGH-GRADE SEROUS PAPILLARY CARCINOMA.

PART 8: LYMPH NODE, RIGHT PERIAORTIC, BIOPSY -

FOUR LYMPH NODES, POSITIVE FOR METASTATIC CARCINOMA (4/4).

PART 9: TUMOR IMPLANT, LEFT, EXCISION -

METASTATIC HIGH-GRADE SEROUS PAPILLARY CARCINOMA.

PART 10: ILEUM, CECUM AND APPENDIX, ILEOCECAL RESECTION AND APPENDECTOMY -

- A. METASTATIC HIGH-GRADE SEROUS PAPILLARY CARCINOMA INVOLVING SEROSAL SURFACES OF ILEUM AND CECUM. PROXIMAL AND DISTAL MARGINS OF RESECTION OF ILEUM ARE NEGATIVE FOR TUMOR.
- B. METASTATIC HIGH-GRADE SEROUS PAPILLARY SEROUS CARCINOMA INVOLVING THE MESOAPPENDIX AND EXTENDING INTO THE SUBMUCOSA OF THE APPENDIX.

PART 11: INTRAPERITONEUM, BIOPSY -

METASTATIC HIGH-GRADE SEROUS PAPILLARY CARCINOMA.

PART 12: PELVIC TUMOR, RESECTION -

METASTATIC HIGH-GRADE SEROUS PAPILLARY CARCINOMA.

PART 13: LYMPH NODE, LEFT PERIAORTIC, BIOPSY -

ONE LYMPH NODE, POSITIVE FOR METASTATIC HIGH-GRADE SEROUS PAPILLARY CARCINOMA (1/1).

PART 14: PERITONEAL SIDEWALL, LEFT, EXCISION -

METASTATIC HIGH-GRADE SEROUS PAPILLARY CARCINOMA.

COMMENT:

#1: The tumor burden is high with extensive involvement of the omentum peritoneal cavity including involvement of the uterine, colonic and ileocecal serosa. Given the involvement of bilateral ovaries, this probably represents the origin of the tumor.

#2: The tumor shows clear cell features in some areas.

##3: Concurrent ascitic fluid is positive for adenocarcinoma.

[page 2 of 2]
CASE SYNOPSIS:

SYNOPTIC - PRIMARY OVARIAN TUMORS INCLUDING BORDERLINE TUMORS

TUMOR LOCATION:	Bilateral
PROCEDURE:	Other: TAH with BSO, Bowel resection, Omentectomy, Appendectomy and staging.
TUMOR SIZE:	Maximum dimension: 5 cm
TUMOR TYPE:	Papillary serous carcinoma
HISTOLOGIC SILVERBERG GRADE:	Poorly differentiated (8-9 pts)
ARCHITECTURAL PATTERN:	Solid (3)
CYTOLOGIC ATYPIA:	Marked (3)
MITOTIC COUNTS / 10hpf:	10-24 (2)
VASCULAR INVASION:	Yes
TUMOR CAPSULE:	Ruptured
SURFACE IMPLANTS:	Invasive
SURFACE IMPLANT SITE:	Uterus, Fallopian Tubes, Omentum, Peritoneal metastasis beyond the pelvis
SURFACE IMPLANT SIZE:	> 2 cm.
MALIGNANT CELLS IN ASCITES OR PERITONEAL WASHING:	Yes
LYMPH NODES EXAMINED:	Total number of lymph nodes examined: 8
LYMPH NODES POSITIVE:	Number of positive lymph nodes, Right: 7 Number of positive lymph nodes, Left: 1
LYMPH NODE GROUPS INVOLVED:	Pelvic, Right, Para-aortic, Right, Para-aortic, Left
EXTRANODAL EXTENSION:	Yes
T STAGE, PATHOLOGIC:	pT3c
N STAGE, PATHOLOGIC:	pN1
M STAGE, PATHOLOGIC:	pMX
FIGO STAGE:	IIIC
Comment:	The tumor appears to arise in a left ovarian cyst which measures 5.0 cm in maximal dimension. However it is extensively metastatic within the peritoneal cavity and involves the anterior abdominal wall.

Source: NCI Genomic Data Commons file 2dcd88c5-e18d-421e-b654-ec6373de695d (TCGA-61-1724.EC0D70E7-672B-425B-A558-D233E0EF1779.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).